Somatic mutation profile of tumor specimen 0DLBMQ from CCDI case PBBZBF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,878 days).
Specimen 0DLBMQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 784685f4-a558-495b-9715-982040fd0acb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLBLY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da61e947-6120-4233-b765-6f3800efbff5

The open-access MAF lists 779 somatic variants for this specimen: 463 protein-altering or splice-affecting, 190 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 407, Silent 190, Intron 83, 3'UTR 28, Nonsense Mutation 28, 5'UTR 11, Splice Region 9, Frame Shift Ins 7, Frame Shift Del 6, Splice Site 4, 5'Flank 2, 3'Flank 2.

Variants (750 of 779; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 165/647 reads (26%) | catalogued as rs772757329, CM159212, COSV54752399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FIG4 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 161/539 reads (30%) | catalogued as rs377357931, CM115116, COSV100020042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRHL3 | c.893G>A p.R298H (on ENST00000350501 / NM_198174.3; = p.R303H on NM_021180.3) | Missense Mutation (SNP) | VAF 153/501 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs752673677, CM140113, COSV52565070; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HK1 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 206/858 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057517928, COSV53863377; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 183/604 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RPE65 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 219/836 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs61752871, CM983758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 360/1044 reads (34%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 261/816 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3967G>A p.A1323T (on ENST00000326724 / NM_001080395.3; = p.A1220T on NM_004920.2) | Missense Mutation (SNP) | VAF 58/846 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs762246513, COSV100352906; called by muse, mutect2
- ABHD16B | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 39/619 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs112134367; called by muse, mutect2
- ACVR1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 284/978 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55122136; called by muse, mutect2, varscan2
- ADAM28 | c.2059C>T p.R687W | Missense Mutation (SNP) | VAF 319/961 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs151293519; called by muse, mutect2, varscan2
- ADAMTS8 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 209/709 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs575136058; called by muse, mutect2, varscan2
- ADD3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 290/872 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1441828066, COSV53323803; called by muse, mutect2, varscan2
- AGAP9 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 138/1450 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1555226001; called by muse, varscan2
- AGPAT2 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 163/605 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as rs771482666, COSV58247838; called by muse, mutect2, varscan2
- ALDH18A1 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 345/1229 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs769823561, COSV64662081; called by muse, mutect2, varscan2
- AMER3 | c.440C>A p.P147Q | Missense Mutation (SNP) | VAF 30/577 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58471381; called by muse, mutect2
- AMHR2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 225/704 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1306686763; called by muse, varscan2
- ANO8 | c.3391G>A p.A1131T | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs1256753662; called by muse, mutect2, varscan2
- ANXA8 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378112224; called by mutect2, varscan2
- APOE | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 156/475 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM064979; called by muse, mutect2, varscan2
- ARHGEF40 | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 242/892 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150936514; called by muse, mutect2, varscan2
- ARMH1 | c.918C>T p.I306= | Splice Region (SNP) | VAF 28/807 reads (3%) | catalogued as rs1192306757; called by muse, mutect2
- ASGR1 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 225/678 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs761235750; called by muse, mutect2, varscan2
- ASTN2 | c.2491G>A p.E831K (on ENST00000313400 / NM_001365069.1; = p.E780K on NM_014010.5) | Missense Mutation (SNP) | VAF 228/702 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs753918178; called by muse, mutect2, varscan2
- ATR | c.4234C>T p.R1412* | Nonsense Mutation (SNP) | VAF 358/1205 reads (30%) | catalogued as rs769216993; called by muse, mutect2, varscan2
- ATRX | c.6590G>A p.R2197H | Missense Mutation (SNP) | VAF 267/394 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64877994; called by muse, mutect2, varscan2
- BAHCC1 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 163/557 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014055054; called by muse, mutect2, varscan2
- BAHCC1 | c.2511C>T p.Y837= | Splice Region (SNP) | VAF 300/653 reads (46%) | catalogued as rs782091380; called by muse, mutect2, varscan2
- BEAN1 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1316507544; called by muse, mutect2
- BIN1 | c.865G>A p.A289T (on ENST00000316724 / NM_001320642.1; = p.A273T on NM_004305.4) | Missense Mutation (SNP) | VAF 223/630 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs779552563, COSV99387610; called by muse, mutect2, varscan2
- BPIFA1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 265/683 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as rs142723109; called by muse, mutect2, varscan2
- BRCA2 | c.7051G>A p.A2351T | Missense Mutation (SNP) | VAF 381/1165 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as rs80358930, COSV66456444; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- C10orf120 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 212/779 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs141554298; called by muse, varscan2
- C1orf210 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 142/379 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs774522331, COSV70682492; called by muse, mutect2, varscan2
- C20orf96 | c.752G>A p.R251H (on ENST00000360321 / NM_153269.3; = p.R250H on NM_080571.1) | Missense Mutation (SNP) | VAF 297/907 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs550866771, COSV100826689; called by muse, mutect2, varscan2
- C9orf78 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 34/1213 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59616712; called by muse, mutect2
- CA3 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 39/1234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279845599, COSV99570906; called by muse, mutect2
- CACNA1H | c.3806G>A p.R1269H | Missense Mutation (SNP) | VAF 158/549 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs749122105; called by muse, mutect2, varscan2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 302/1065 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2, varscan2
- CBARP | c.430+7G>A | Splice Region (SNP) | VAF 193/581 reads (33%) | catalogued as rs748030029, COSV99289386; called by muse, mutect2, varscan2
- CCDC107 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 191/615 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1199534720; called by muse, mutect2, varscan2
- CD1B | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 217/569 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs760467639; called by muse, mutect2, varscan2
- CDC26 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 228/817 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs199571847; called by muse, varscan2
- CDH12 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 138/556 reads (25%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.847); catalogued as rs765722528; called by muse, mutect2, varscan2
- CDH9 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 205/719 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs778204468, COSV50488840; called by muse, mutect2, varscan2
- CDK12 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 645/1360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71000304; called by muse, mutect2, varscan2
- CDK13 | c.2957G>A p.R986H | Missense Mutation (SNP) | VAF 32/1134 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51702464; called by muse, mutect2
- CDKL4 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 245/853 reads (29%) | catalogued as rs771548328, COSV101115322, COSV66509906; called by muse, mutect2, varscan2
- CEACAM1 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 145/414 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs373994942; called by muse, mutect2, varscan2
- CERCAM | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 221/720 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761539491; called by muse, mutect2, varscan2
- CFAP65 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 199/607 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs772580549; called by muse, mutect2, varscan2
- CFAP97 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 371/727 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192418727, COSV71712879; called by muse, mutect2, varscan2
- CHAF1B | c.1062-4G>A | Splice Region (SNP) | VAF 262/877 reads (30%) | catalogued as rs375351314; called by muse, mutect2, varscan2
- CHD1 | c.4912C>T p.R1638W | Missense Mutation (SNP) | VAF 260/912 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs141316125; called by muse, mutect2, varscan2
- CHD6 | c.7673C>T p.T2558M | Missense Mutation (SNP) | VAF 375/1186 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs760202675; called by muse, mutect2, varscan2
- CLASRP | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 163/587 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs935094801, COSV99673525; called by muse, mutect2, varscan2
- CLCN7 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 127/383 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs762729630; called by muse, mutect2, varscan2
- CNOT2 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 399/1095 reads (36%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1161007517, COSV57500539; called by muse, mutect2, varscan2
- CNOT8 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 52/952 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99597246; called by muse, mutect2
- COL6A1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 199/645 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as rs568865339, COSV62616088; called by muse, mutect2, varscan2
- COPE | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 143/458 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs536383915, COSV53229642; called by muse, mutect2, varscan2
- CORO7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 164/609 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs527794334, COSV52031064; called by muse, mutect2, varscan2
- CP | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 28/1012 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1286440771, COSV52829767; called by muse, mutect2
- CRTC1 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 245/695 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs541331056; called by muse, mutect2, varscan2
- CSMD1 | c.8281G>A p.V2761M (on ENST00000520002; = p.V2760M on NM_033225.6) | Missense Mutation (SNP) | VAF 291/975 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753927140, COSV59279948; called by muse, mutect2, varscan2
- CSMD2 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 207/738 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as rs200640948, COSV99592858; called by muse, mutect2, varscan2
- CSNK1G2 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 156/447 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.953); catalogued as rs1020811832; called by muse, mutect2, varscan2
- CUBN | c.4726C>T p.R1576C | Missense Mutation (SNP) | VAF 322/1018 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as rs765770899; called by muse, mutect2, varscan2
- CUL7 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 209/649 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs761386869, COSV54814025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CXCL9 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 454/993 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1375851280, COSV53578486; called by muse, mutect2, varscan2
- CYC1 | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 153/480 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1391326974; called by muse, mutect2, varscan2
- CYFIP1 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 322/1133 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs751438013; called by muse, mutect2, varscan2
- DAGLA | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 139/467 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99944566; called by muse, mutect2, varscan2
- DBP | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 250/703 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773736859; called by muse, mutect2, varscan2
- DCST1 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 156/520 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs760388090, COSV55060840; called by muse, varscan2
- DDX27 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 270/897 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs761670353; called by muse, mutect2, varscan2
- DENND2A | c.2327+7G>A | Splice Region (SNP) | VAF 298/965 reads (31%) | catalogued as rs773384220; called by muse, mutect2, varscan2
- DHRS11 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 24/678 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs145372121; called by muse, mutect2
- DIP2C | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 144/518 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs903089111, COSV55154478; called by muse, mutect2, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 74/244 reads (30%) | catalogued as rs756156984; called by mutect2, varscan2
- DMBX1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 261/818 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs749749952, COSV63602627; called by muse, mutect2, varscan2
- DNAH10 | c.11876G>A p.R3959Q (on ENST00000409039; = p.R3898Q on NM_207437.3) | Missense Mutation (SNP) | VAF 340/1140 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as rs1051360754, COSV101292217, COSV68989681; called by muse, varscan2
- DNAH2 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 288/951 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs552122897, COSV66719126; called by muse, mutect2, varscan2
- DNAJC27 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 419/1257 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs1378459089, COSV53096909; called by muse, mutect2, varscan2
- DRICH1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 202/731 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs764669789, COSV58503825; called by muse, mutect2, varscan2
- DSCAML1 | c.5408G>A p.R1803Q (on ENST00000321322; = p.R1743Q on NM_020693.4) | Missense Mutation (SNP) | VAF 195/562 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs151098218; called by muse, mutect2, varscan2
- DVL1 | c.1301G>A p.R434H (on ENST00000378888 / NM_001330311.2; = p.R409H on NM_004421.3) | Missense Mutation (SNP) | VAF 164/559 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867732546, COSV59563437; called by muse, mutect2, varscan2
- DYRK1B | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 34/998 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59915319; called by muse, mutect2
- DYSF | c.3115C>T p.R1039W | Missense Mutation (SNP) | VAF 280/773 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760443264, COSV99245862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF4 | c.544G>A p.V182I (on ENST00000609451; = p.V178I on NM_001110514.1) | Missense Mutation (SNP) | VAF 290/811 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs750568027, COSV104418083; called by muse, mutect2, varscan2
- EDC4 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 275/610 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs753348821, COSV62768375; called by muse, mutect2, varscan2
- EEF1AKNMT | c.2086G>A p.V696M (on ENST00000361735 / NM_015935.5; = p.V610M on NM_014955.3) | Missense Mutation (SNP) | VAF 214/625 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs1353959628; called by muse, mutect2, varscan2
- EEF2K | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 178/587 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775024005; called by muse, mutect2, varscan2
- EGFL8 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 250/701 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs750706339; called by muse, mutect2, varscan2
- EHBP1L1 | c.3484G>A p.V1162M | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1378204814, COSV58574630; called by muse, mutect2, varscan2
- EIF3A | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 277/946 reads (29%) | catalogued as COSV64961053; called by muse, mutect2, varscan2
- EIF4A1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 373/1344 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1414585747, COSV51510239; called by muse, mutect2
- EIF4G2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 310/1157 reads (27%) | catalogued as COSV100379325; called by muse, mutect2, varscan2
- ELAVL3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 246/751 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323747400, COSV63645684; called by muse, mutect2, varscan2
- ELFN2 | c.2053G>A p.G685S | Missense Mutation (SNP) | VAF 182/498 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs763031057; called by muse, mutect2, varscan2
- EMILIN2 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 112/311 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1288603795; called by muse, mutect2, varscan2
- EOGT | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 250/841 reads (30%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.914); catalogued as rs1008223582, COSV99808669; called by muse, mutect2, varscan2
- EPHA2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 332/1016 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1387273351, COSV64452446; called by muse, mutect2, varscan2
- EPHB2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 172/631 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs370909083; called by muse, mutect2, varscan2
- EPHB4 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 157/574 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs754054238; called by muse, mutect2, varscan2
- EPPK1 | c.2827C>T p.R943W | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs369413834; called by muse, mutect2, varscan2
- EPX | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 84/1047 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs191966823, COSV99836296; called by muse, mutect2
- EPX | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 552/1225 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs757551690, COSV56595325; called by muse, mutect2, varscan2
- EVX2 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 109/427 reads (26%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV100420892; called by muse, varscan2
- FANCA | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 46/772 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs371351450; ClinVar: uncertain significance; called by muse, mutect2
- FARP1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 257/698 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60335545; called by muse, mutect2, varscan2
- FARS2 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 309/877 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747278433; called by muse, mutect2, varscan2
- FBXL3 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 148/594 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772342610, COSV62919050; called by muse, mutect2, varscan2
- FBXO30 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 216/721 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1228295014, COSV52791674; called by muse, mutect2, varscan2
- FBXO31 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 252/535 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342616722, COSV61149789; called by muse, mutect2, varscan2
- FBXO38 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 224/741 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.617); catalogued as rs779438870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FEN1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 233/769 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765464647; called by muse, mutect2, varscan2
- FER1L5 | c.2047G>A p.V683M (on ENST00000623019; = p.V688M on NM_001293083.2) | Missense Mutation (SNP) | VAF 199/631 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs368217243; called by muse, mutect2, varscan2
- FES | c.1034C>T p.T345I | Missense Mutation (SNP) | VAF 138/402 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs756511039; called by muse, mutect2, varscan2
- FGD5 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 175/499 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.226); catalogued as rs375026840; called by muse, mutect2, varscan2
- FGFR4 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 92/348 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs1562071377, COSV52802806; called by muse, mutect2
- FIP1L1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 298/1722 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1355761572, COSV60995018; called by muse, mutect2, varscan2
- FLT4 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 212/769 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs140347743, COSV56113367; called by muse, mutect2, varscan2
- FN1 | c.5462G>A p.R1821H | Missense Mutation (SNP) | VAF 251/809 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs775421803; called by muse, mutect2, varscan2
- FOSL2 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 293/942 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305140602, COSV53103916, COSV53104289; called by muse, mutect2, varscan2
- FZR1 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 138/450 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763545974; called by muse, mutect2, varscan2
- GAB1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 347/723 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762061638; called by muse, mutect2, varscan2
- GBA2 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 233/748 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV62306315; called by muse, mutect2, varscan2
- GCKR | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 351/1102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs775857392; called by muse, mutect2, varscan2
- GGA2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 292/1026 reads (28%) | catalogued as rs370781819; called by muse, mutect2, varscan2
- GGA3 | c.1756G>A p.V586M (on ENST00000537686 / NM_138619.4; = p.V553M on NM_014001.5) | Missense Mutation (SNP) | VAF 587/1218 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771395482; called by muse, mutect2, varscan2
- GLI2 | c.3830C>T p.T1277M (on ENST00000361492 / NM_001374353.1; = p.T1294M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/534 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.028); catalogued as rs767608623, COSV58050679; called by muse, mutect2, varscan2
- GNB3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 320/944 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1184436054; called by muse, mutect2, varscan2
- GOLGA8J | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs1266150997; called by mutect2, varscan2
- GPAT2 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 58/1092 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746504005; called by muse, mutect2
- GPR33 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 26/879 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs796119394; called by muse, mutect2
- GRIK5 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 232/781 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs782676116; called by muse, mutect2, varscan2
- GRM3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 233/595 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs184377536, COSV64469399; called by muse, mutect2, varscan2
- H1-7 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 28/838 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1398378737; called by muse, mutect2
- H3-5 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 319/859 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs148314204, COSV61186704; called by muse, mutect2, varscan2
- H6PD | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 190/574 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs148493577; called by muse, mutect2, varscan2
- HCFC1 | c.4814C>T p.T1605M | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1405940157; called by muse, mutect2
- HDAC2 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 178/587 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1159764466; called by muse, varscan2
- HNRNPM | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 190/545 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs778066842, COSV55314213; called by muse, mutect2, varscan2
- HPR | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 56/814 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1379782150; called by muse, mutect2
- HTR2C | c.383C>G p.P128R | Missense Mutation (SNP) | VAF 285/420 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569499428; called by muse, mutect2, varscan2
- HUS1B | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 236/680 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57871566; called by muse, mutect2, varscan2
- IBA57 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 206/592 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as rs371751844; called by muse, mutect2, varscan2
- IDH3A | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 400/1282 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs762865075, COSV51904326; called by muse, mutect2, varscan2
- IGFBP2 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 181/548 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs759413522, COSV99288284; called by muse, mutect2, varscan2
- IL18RAP | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 402/1152 reads (35%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs768468042, COSV51823778; called by muse, mutect2, varscan2
- INCENP | c.1729C>T p.R577C (on ENST00000394818 / NM_001040694.2; = p.R573C on NM_020238.3) | Missense Mutation (SNP) | VAF 88/564 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs745742196, COSV53918281; called by muse, varscan2
- INTS6L | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 242/383 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100878353, COSV66084091, COSV66086619; called by muse, mutect2, varscan2
- IQSEC1 | c.2497G>A p.G833R | Missense Mutation (SNP) | VAF 384/1222 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs139635176; called by muse, mutect2, varscan2
- IRX1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57358038; called by muse, mutect2, varscan2
- ITCH | c.1529G>A p.R510H (on ENST00000262650 / NM_001257137.3; = p.R469H on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 301/961 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765813305, COSV52930911; called by muse, mutect2, varscan2
- ITPR2 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 280/792 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370751866; called by muse, mutect2, varscan2
- ITPR3 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 135/465 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100966977; called by muse, mutect2, varscan2
- KALRN | c.8353C>T p.R2785* (on ENST00000360013 / NM_001024660.4; = p.R1088* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 320/978 reads (33%) | catalogued as rs201835992, COSV99360706; called by muse, varscan2
- KASH5 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 98/311 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs201032080; called by muse, mutect2, varscan2
- KCNA7 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as rs541248038, COSV55502864; called by muse, mutect2, varscan2
- KCNH3 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 187/631 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs770756585; called by muse, mutect2, varscan2
- KCNJ11 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 65/418 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780511484, COSV60594091; called by muse, mutect2, varscan2
- KCNV1 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 313/701 reads (45%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.998); catalogued as rs756504582, COSV52084851; called by muse, mutect2, varscan2
- KCNV2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 205/540 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1342075631, COSV101172610; called by muse, mutect2, varscan2
- KCTD13 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 232/736 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs199647677; called by muse, varscan2
- KDM4B | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 26/710 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1206749582, COSV50214808; called by muse, mutect2
- KIF19 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 219/971 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as rs201212996, COSV63429548; called by muse, mutect2, varscan2
- KLHL35 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 171/550 reads (31%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.54); catalogued as rs375470750; called by muse, mutect2, varscan2
- KMT2C | c.14107G>A p.V4703I | Missense Mutation (SNP) | VAF 385/1195 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369684496, COSV51502820; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 308/913 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as rs543574061, COSV52860790; called by muse, mutect2, varscan2
- KRT7 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 233/827 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs771441481, COSV57765941; called by muse, mutect2, varscan2
- LARP6 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 201/675 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as rs200378737; called by muse, mutect2, varscan2
- LDB3 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 243/844 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs61857115; ClinVar: uncertain significance; called by muse, varscan2
- LMTK2 | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 286/859 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291773145, COSV51990952; called by muse, mutect2, varscan2
- LPCAT4 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 265/797 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752945059, COSV59218209; called by muse, mutect2, varscan2
- LPIN3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 146/807 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs772847019; called by muse, mutect2, varscan2
- LRFN3 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 107/360 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs560324400; called by muse, varscan2
- LRFN3 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 165/514 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1346581668, COSV55817866; called by muse, varscan2
- LRRC70 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 214/742 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1439025161; called by muse, mutect2, varscan2
- LRRN2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 180/489 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs780781216, COSV65784659; called by muse, mutect2, varscan2
- LSM10 | c.362dup p.N121Kfs*3 | Frame Shift Ins (INS) | VAF 183/627 reads (29%) | catalogued as rs768776995; called by mutect2, pindel, varscan2
- LTB4R | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 149/594 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51866460; called by muse, mutect2, varscan2
- LYST | c.7322A>G p.N2441S | Missense Mutation (SNP) | VAF 217/794 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs752896052; called by muse, mutect2, varscan2
- MAF1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 213/605 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59364603; called by muse, mutect2, varscan2
- MAP3K21 | c.1603C>T p.R535W | Missense Mutation (SNP) | VAF 342/1078 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64041014; called by muse, varscan2
- MAPK8IP2 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 141/515 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs774267045, COSV50501772; called by muse, mutect2, varscan2
- MARK3 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 246/741 reads (33%) | catalogued as rs763214749, COSV53509356; called by muse, mutect2, varscan2
- MDC1 | c.3874C>T p.R1292W | Missense Mutation (SNP) | VAF 203/645 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs547239956; called by muse, mutect2, varscan2
- MED13L | c.4028C>T p.T1343M | Missense Mutation (SNP) | VAF 429/1256 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs745839062; called by muse, mutect2, varscan2
- MED17 | c.176A>C p.E59A | Missense Mutation (SNP) | VAF 19/551 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1321894095, COSV52599535; called by muse, mutect2
- MED24 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 432/895 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs761221311; called by muse, mutect2, varscan2
- MFHAS1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 24/458 reads (5%) | catalogued as COSV99359550; called by muse, mutect2
- MID1 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 317/499 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201454444, COSV58191431; called by muse, mutect2, varscan2
- MIEF2 | c.294del p.S99Rfs*15 | Frame Shift Del (DEL) | VAF 247/733 reads (34%) | catalogued as COSV58946017; called by mutect2, varscan2
- MOV10 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 379/1036 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209761297; called by muse, mutect2, varscan2
- MPPE1 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 158/557 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs926176134, COSV52328137; called by muse, mutect2, varscan2
- MPZL2 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 248/869 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV54048586; called by muse, mutect2, varscan2
- MTCL1 | c.2488C>T p.R830C (on ENST00000306329 / NM_001378206.1; = p.R470C on NM_015210.4) | Missense Mutation (SNP) | VAF 29/496 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs201898483; called by muse, mutect2
- MTCL1 | c.4223C>T p.P1408L (on ENST00000306329 / NM_001378206.1; = p.P1089L on NM_015210.4) | Missense Mutation (SNP) | VAF 73/1156 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs145193610; called by muse, mutect2
- MTMR3 | c.3380C>T p.A1127V | Missense Mutation (SNP) | VAF 349/1062 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs960493319, COSV60303828; called by muse, mutect2, varscan2
- MTMR6 | c.27C>T p.V9= | Splice Region (SNP) | VAF 157/498 reads (32%) | catalogued as rs746300978, COSV67808314; called by muse, mutect2, varscan2
- MTOR | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 215/1145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63872788; called by muse, mutect2, varscan2
- MUC5B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 220/687 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs763022013; called by muse, mutect2, varscan2
- MYH14 | c.5951C>T p.P1984L | Missense Mutation (SNP) | VAF 200/546 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs772690371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLIP | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 282/1046 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201953912; called by muse, mutect2, varscan2
- MYO1C | c.511C>T p.R171W (on ENST00000648651 / NM_001080779.2; = p.R136W on NM_033375.5) | Missense Mutation (SNP) | VAF 202/672 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs141250212; called by muse, mutect2, varscan2
- MYO9B | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 162/548 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1256773188, COSV68278285; called by muse, mutect2, varscan2
- MYOM3 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 207/632 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs780827849; called by muse, mutect2, varscan2
- MYORG | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1264814966, COSV52628397; called by muse, varscan2
- NCF1 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 150/455 reads (33%) | catalogued as rs1446986189, CM083736; called by muse, mutect2, varscan2
- NDUFA4L2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 280/755 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs374412878; called by muse, mutect2, varscan2
- NDUFB7 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 110/353 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs758427722; called by muse, mutect2, varscan2
- NFE2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 158/503 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs368417462; called by muse, mutect2, varscan2
- NTSR1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 167/577 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1208532915, COSV65138047; called by muse, mutect2, varscan2
- NWD1 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 129/403 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs777000586; called by muse, mutect2, varscan2
- OR6B1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 366/1079 reads (34%) | catalogued as rs745433880, COSV68770009; called by muse, mutect2, varscan2
- OR6F1 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 294/953 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV100129231; called by muse, mutect2, varscan2
- PACRG | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 304/930 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs763185634, COSV61295233; called by muse, varscan2
- PADI4 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 36/928 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs767499070, COSV64922903; called by muse, mutect2
- PASK | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 48/970 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs774797247; called by muse, mutect2
- PCBP2 | c.914G>A p.R305H (on ENST00000439930 / NM_001128911.2; = p.R306H on NM_005016.6) | Missense Mutation (SNP) | VAF 221/716 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63727838; called by muse, mutect2, varscan2
- PCDHGA12 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 258/799 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52759985; called by muse, mutect2, varscan2
- PCDHGB6 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 180/539 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV54046219; called by muse, mutect2, varscan2
- PCNX2 | c.3946C>T p.H1316Y | Missense Mutation (SNP) | VAF 340/981 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs754079857, COSV50836927; called by muse, mutect2, varscan2
- PDE4D | c.1292G>A p.R431Q (on ENST00000340635 / NM_001104631.2; = p.R295Q on NM_006203.4) | Missense Mutation (SNP) | VAF 138/482 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs767902478; called by muse, mutect2, varscan2
- PDE4DIP | c.3844C>T p.R1282* | Nonsense Mutation (SNP) | VAF 170/1259 reads (14%) | catalogued as rs587653191; called by muse, mutect2, varscan2
- PDGFRA | c.1319C>T p.T440M | Missense Mutation (SNP) | VAF 560/2730 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs143344944, COSV57265372; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- PDIA5 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 197/742 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374477364; called by muse, mutect2, varscan2
- PHACTR2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 516/1393 reads (37%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs566532922, COSV59855684; called by muse, mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 127/628 reads (20%) | catalogued as rs761575760; called by pindel, varscan2
- PHRF1 | c.2896G>A p.V966M (on ENST00000264555 / NM_001286581.2; = p.V965M on NM_020901.4) | Missense Mutation (SNP) | VAF 164/545 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1428290442; called by muse, mutect2, varscan2
- PIGQ | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs751055581; called by muse, mutect2, varscan2
- PITPNM3 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 167/556 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs144918108; called by muse, mutect2, varscan2
- PKD1 | c.11780G>A p.R3927H (on ENST00000262304 / NM_001009944.3; = p.R3926H on NM_000296.4) | Missense Mutation (SNP) | VAF 173/552 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as rs1489338153, COSV51922462; called by muse, varscan2
- PKD1 | c.10637G>A p.R3546Q (on ENST00000262304 / NM_001009944.3; = p.R3545Q on NM_000296.4) | Missense Mutation (SNP) | VAF 178/514 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs746925335, CD1210710; called by muse, mutect2, varscan2
- PKLR | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 248/805 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368830326; called by muse, mutect2, varscan2
- PLEC | c.6506C>T p.S2169L (on ENST00000322810 / NM_201380.4; = p.S2059L on NM_000445.5) | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); catalogued as rs782658240; ClinVar: uncertain significance; called by muse, mutect2
- PLK1 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 243/818 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs757330190; called by muse, mutect2, varscan2
- POLM | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 82/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1322439420, COSV99641661; called by muse, mutect2, varscan2
- POLR2A | c.1997G>A p.R666H | Missense Mutation (SNP) | VAF 282/912 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.94); catalogued as rs1567703214; called by muse, mutect2, varscan2
- POLR3E | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 129/446 reads (29%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.94); catalogued as rs771336397, COSV55400476; called by muse, mutect2, varscan2
- POLRMT | c.3568C>T p.R1190W | Missense Mutation (SNP) | VAF 146/500 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs745935945; called by muse, mutect2, varscan2
- POU5F1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/460 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs750853618; called by muse, mutect2
- PPP1R37 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs868324587; called by muse, mutect2, varscan2
- PRMT5 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 302/859 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs753096989, COSV53548284, COSV99363029; called by muse, mutect2, varscan2
- PROX1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 369/1104 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV54776614; called by muse, mutect2, varscan2
- PROZ | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 225/733 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs141140968; called by muse, mutect2, varscan2
- PRRT4 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 160/574 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1057356425, COSV71054655; called by muse, mutect2, varscan2
- PRSS36 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 177/588 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752005326; called by muse, mutect2, varscan2
- PSD2 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 250/909 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs547591794, COSV51211147; called by muse, mutect2, varscan2
- PSMB5 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 54/403 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs561234583, COSV57800243; called by muse, mutect2, varscan2
- PTCH2 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 126/376 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs766965501; called by muse, mutect2, varscan2
- PTCHD3 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 223/610 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs753562999; called by muse, mutect2, varscan2
- PTCHD4 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 271/866 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs770152940; called by muse, mutect2, varscan2
- PTK7 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 253/851 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779250545, COSV100030055; called by muse, mutect2, varscan2
- PXDNL | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 182/456 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs776253984, COSV100680683, COSV62484758; called by muse, mutect2, varscan2
- PYGM | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 142/431 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs769479715, COSV99376579; called by muse, mutect2, varscan2
- RAB19 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 218/618 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144362151; called by muse, mutect2, varscan2
- RERE | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 213/647 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1359424164, COSV61946190; called by muse, mutect2, varscan2
- RIMS2 | c.3164G>A p.R1055H (on ENST00000666250 / NM_001348490.2; = p.R863H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 338/746 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs199562210, COSV51667384; called by muse, varscan2
- RNF113B | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 114/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99940402; called by muse, mutect2, varscan2
- RPS3 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 305/902 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs747317928, COSV53705278; called by muse, mutect2, varscan2
- RPTOR | c.3104C>T p.T1035M | Missense Mutation (SNP) | VAF 415/840 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as rs776174012, COSV60802560; called by muse, mutect2
- RRN3 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 205/727 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs746484179; called by muse, mutect2, varscan2
- RUNDC3A | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 284/642 reads (44%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs1417453697, COSV56637017; called by muse, mutect2, varscan2
- RYR1 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 212/733 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs558969466, COSV62102938; called by mutect2, varscan2
- SARAF | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 323/1003 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200334339; called by muse, mutect2, varscan2
- SCAF1 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs892718060; called by muse, mutect2, varscan2
- SCARA5 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 238/705 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241119460; called by muse, mutect2, varscan2
- SCMH1 | c.1372C>T p.R458C (on ENST00000326197 / NM_001031694.2; = p.R411C on NM_012236.4) | Missense Mutation (SNP) | VAF 329/1052 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs369045955; called by muse, mutect2, varscan2
- SCN8A | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 243/837 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as rs771976211; called by muse, mutect2, varscan2
- SCRIB | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 218/734 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs138684024; called by muse, mutect2, varscan2
- SEMA4D | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 122/438 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs753165801, COSV59393287; called by muse, mutect2, varscan2
- SETDB1 | c.3571G>A p.A1191T | Missense Mutation (SNP) | VAF 267/741 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.184); catalogued as rs145276744; called by muse, mutect2, varscan2
- SFRP4 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 268/961 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs146871972; called by muse, mutect2, varscan2
- SHROOM4 | c.4094A>G p.Y1365C | Missense Mutation (SNP) | VAF 255/396 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557247046; called by muse, mutect2, varscan2
- SLC22A18 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749161303, COSV56541714; called by muse, mutect2, varscan2
- SLC25A12 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 331/1058 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1342116730, COSV55535744; called by muse, mutect2, varscan2
- SLC4A7 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 252/974 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs770371932; called by muse, mutect2, varscan2
- SLC6A9 | c.1729C>T p.R577C (on ENST00000360584 / NM_201649.4; = p.R523C on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 215/737 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs773894277, COSV100746585; called by muse, mutect2, varscan2
- SLCO4A1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 161/474 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs762226385, COSV53891143; called by muse, mutect2, varscan2
- SLCO4C1 | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 265/884 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546037634; called by muse, mutect2, varscan2
- SLITRK4 | c.2338C>T p.R780C | Missense Mutation (SNP) | VAF 363/627 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs782309385, COSV62023243; called by muse, mutect2, varscan2
- SMARCA5 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 359/703 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51648325; called by muse, mutect2, varscan2
- SOCS6 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 206/682 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs201670304; called by muse, varscan2
- SOHLH1 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 222/740 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs572151479, COSV53684234; called by muse, mutect2, varscan2
- SORCS3 | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 271/904 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767166140; called by muse, mutect2, varscan2
- SPTAN1 | c.2197C>T p.R733* | Nonsense Mutation (SNP) | VAF 247/676 reads (37%) | catalogued as COSV63985289; called by muse, mutect2, varscan2
- SPTBN2 | c.6110G>A p.R2037H | Missense Mutation (SNP) | VAF 185/591 reads (31%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.915); catalogued as rs144215906; called by muse, mutect2, varscan2
- SRPK3 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 27/644 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782314376; called by muse, mutect2
- SRPK3 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs200511882; called by muse, mutect2
- SRPX2 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 204/295 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs368571175, COSV52167994; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ST14 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 235/610 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs770523713; called by muse, mutect2, varscan2
- ST3GAL6 | c.517dup p.S173Ffs*7 | Frame Shift Ins (INS) | VAF 343/1176 reads (29%) | catalogued as rs757665003; called by mutect2, pindel, varscan2
- STARD9 | c.10904C>T p.T3635M | Missense Mutation (SNP) | VAF 214/609 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs997284228; called by muse, mutect2, varscan2
- STAT3 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 398/928 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.989); catalogued as rs1356637796; ClinVar: uncertain significance; called by muse, varscan2
- STK4 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 39/985 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs1014058732; called by muse, mutect2
- STX17 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 273/989 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs199793363; called by muse, mutect2, varscan2
- SULT1A2 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747555025, COSV57682607; called by muse, mutect2, varscan2
- SUN1 | c.2078G>A p.R693H (on ENST00000405266 / NM_001367651.1; = p.R573H on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 227/719 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769143587, COSV67450392; called by muse, mutect2, varscan2
- SYMPK | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 126/487 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs376169646; called by muse, mutect2, varscan2
- SZT2 | c.6361C>T p.R2121* (on ENST00000634258 / NM_001365999.1; = p.R2064* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 211/740 reads (29%) | catalogued as rs550692594, COSV100987713; called by muse, mutect2, varscan2
- SZT2 | c.8224C>T p.R2742C (on ENST00000634258 / NM_001365999.1; = p.R2685C on NM_015284.4) | Missense Mutation (SNP) | VAF 188/692 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs760152706; called by muse, mutect2, varscan2
- TAF1D | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 73/568 reads (13%) | catalogued as rs948843593; called by muse, mutect2, varscan2
- TBC1D10B | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 205/610 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs575661025; called by muse, mutect2, varscan2
- TBC1D13 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 188/613 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775338876, COSV56353548; called by muse, mutect2, varscan2
- TBC1D9B | c.3098C>T p.T1033M (on ENST00000356834 / NM_198868.3; = p.T1016M on NM_015043.4) | Missense Mutation (SNP) | VAF 153/542 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773516159; called by muse, mutect2, varscan2
- TBCD | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 141/666 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as rs755381482, COSV104416575; called by muse, mutect2, varscan2
- TDRD15 | c.5734G>A p.A1912T | Missense Mutation (SNP) | VAF 232/730 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1481283888; called by muse, varscan2
- TENM3 | c.7856G>A p.R2619H | Missense Mutation (SNP) | VAF 232/427 reads (54%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs1214038143, COSV69299013; called by muse, mutect2, varscan2
- TENT5B | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs767819598; called by muse, mutect2, varscan2
- TFG | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 389/1208 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99561065; called by muse, mutect2, varscan2
- THEMIS | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 46/994 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200529297, COSV64069470; called by muse, mutect2
- THSD7A | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 218/656 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1320096867, COSV70261585; called by muse, mutect2, varscan2
- THYN1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 166/561 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443158035; called by muse, mutect2, varscan2
- TIAM1 | c.4445G>A p.R1482Q | Missense Mutation (SNP) | VAF 201/660 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs746172852; called by muse, mutect2, varscan2
- TINAGL1 | c.940C>T p.R314* | Nonsense Mutation (SNP) | VAF 181/661 reads (27%) | catalogued as rs1436224085, COSV54699748; called by muse, mutect2, varscan2
- TLN2 | c.3580G>A p.V1194I | Missense Mutation (SNP) | VAF 191/578 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs369431778; called by muse, mutect2, varscan2
- TMEM120A | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 189/603 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782082182; called by muse, mutect2, varscan2
- TNK1 | c.1492+1G>C p.X498_splice (on ENST00000576812 / NM_001251902.2; = p.X493_splice on NM_003985.5) | Splice Site (SNP) | VAF 150/457 reads (33%) | catalogued as rs777104604; called by muse, mutect2, varscan2
- TNXB | c.11473G>A p.V3825M (on ENST00000647633; = p.V3578M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/895 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769461206, COSV64486666; called by muse, mutect2, varscan2
- TRIM77 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 214/737 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs962384490; called by muse, mutect2, varscan2
- TRIP11 | c.3632G>A p.R1211H | Missense Mutation (SNP) | VAF 293/1083 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773081864, COSV50959521; called by muse, mutect2, varscan2
- TRIT1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 424/1257 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs201156716; called by muse, mutect2, varscan2
- TRPM3 | c.2887C>T p.R963C (on ENST00000357533 / NM_001366142.2; = p.R806C on NM_020952.6) | Missense Mutation (SNP) | VAF 276/1034 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755862358, COSV62585911, COSV62592104; called by muse, mutect2, varscan2
- TSPEAR | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 221/694 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1408279122; called by muse, mutect2, varscan2
- TTN | c.78011G>A p.R26004H (on ENST00000591111; = p.R18580H on NM_003319.4) | Missense Mutation (SNP) | VAF 401/1163 reads (34%) | PolyPhen probably damaging (0.998); catalogued as rs766522109, COSV100603504; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.62650G>A p.A20884T (on ENST00000591111; = p.A13460T on NM_003319.4) | Missense Mutation (SNP) | VAF 246/952 reads (26%) | PolyPhen possibly damaging (0.651); catalogued as COSV59936846; called by muse, mutect2, varscan2
- TUBGCP3 | c.2597C>T p.T866M | Missense Mutation (SNP) | VAF 193/657 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs146149063; called by muse, mutect2, varscan2
- UBR5 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 416/1143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774700827, COSV55288603, COSV55290696; called by muse, mutect2, varscan2
- ULK4 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 358/1091 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764647463, COSV57205731; called by muse, mutect2, varscan2
- UNC13C | c.3283A>G p.T1095A | Missense Mutation (SNP) | VAF 248/877 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs775670591; called by muse, varscan2
- USP21 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 222/703 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.63); catalogued as rs780961535, COSV57091564; called by muse, mutect2, varscan2
- USP32 | c.3719G>A p.R1240H | Missense Mutation (SNP) | VAF 88/1878 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs145690333; called by muse, mutect2
- VPS13C | c.2111C>T p.T704M (on ENST00000644861 / NM_020821.3; = p.T661M on NM_017684.5) | Missense Mutation (SNP) | VAF 271/943 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs114387705; called by muse, mutect2, varscan2
- VPS41 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 268/913 reads (29%) | catalogued as rs555404379; called by muse, mutect2, varscan2
- WDTC1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 208/714 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1277681248; called by muse, mutect2, varscan2
- XYLB | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 228/884 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs559792550; called by muse, mutect2, varscan2
- YTHDC2 | c.3004C>T p.R1002* | Nonsense Mutation (SNP) | VAF 56/1192 reads (5%) | catalogued as COSV99363218; called by muse, mutect2
- ZC3HAV1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 246/760 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs551302731, COSV99649075; called by muse, mutect2, varscan2
- ZMIZ1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 206/510 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV57899767; called by muse, mutect2, varscan2
- ZNF248 | c.1735T>C p.S579P | Missense Mutation (SNP) | VAF 308/1080 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs200078689; called by muse, mutect2, varscan2
- ZNF444 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61363744; called by muse, mutect2, varscan2
- ZNF446 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 124/369 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs376903864; called by muse, mutect2, varscan2
- ZNF546 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 60/609 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs777358042, COSV61259345; called by muse, mutect2, varscan2
- ZNF672 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 197/557 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100129361; called by muse, mutect2, varscan2
- ZNF696 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs1045938933; called by muse, mutect2
- ZNF74 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 251/594 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199814477, COSV62621583; called by muse, mutect2, varscan2
- ZNF775 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 169/493 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs1036175864; called by muse, mutect2, varscan2
- ABCA12 | c.2741T>C p.L914P (on ENST00000272895 / NM_173076.3; = p.L596P on NM_015657.3) | Missense Mutation (SNP) | VAF 405/1352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- APC2 | c.6106G>A p.V2036I | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ARHGAP45 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 178/494 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ARID3A | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 148/499 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARVCF | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 27/933 reads (3%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.2); called by muse, mutect2
- ASPH | c.1661del p.G554Dfs*14 | Frame Shift Del (DEL) | VAF 319/1166 reads (27%) | called by mutect2, pindel, varscan2
- ATF7 | c.997C>T p.R333* (on ENST00000548446 / NM_001366555.2; = p.R322* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 250/704 reads (36%) | called by mutect2, varscan2
- ATG9A | c.993C>A p.C331* | Nonsense Mutation (SNP) | VAF 101/530 reads (19%) | called by muse, mutect2, varscan2
- ATN1 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 139/417 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- BLK | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 176/644 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C19orf47 | c.418T>C p.S140P | Missense Mutation (SNP) | VAF 175/507 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- CAPN15 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CFAP100 | c.709A>G p.T237A | Missense Mutation (SNP) | VAF 131/461 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CILK1 | c.1707dup p.E570Rfs*41 (on ENST00000350082 / NM_001375397.1; = p.E563Rfs*41 on NM_014920.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 437/1428 reads (31%) | called by mutect2, pindel, varscan2
- CLPP | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 80/262 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by mutect2, varscan2
- CTR9 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 132/1676 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2
- CYP2F1 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 136/579 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- DCDC1 | c.2215T>A p.Y739N | Missense Mutation (SNP) | VAF 350/1088 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- DHX16 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 301/932 reads (32%) | called by muse, mutect2, varscan2
- DIXDC1 | c.751G>T p.G251* (on ENST00000440460 / NM_001037954.4; = p.G40* on NM_033425.4) | Nonsense Mutation (SNP) | VAF 100/1133 reads (9%) | called by muse, mutect2
- DMWD | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- DNAH3 | c.6281del p.N2094Ifs*39 | Frame Shift Del (DEL) | VAF 214/829 reads (26%) | called by pindel, varscan2
- DSG2 | c.1554G>T p.E518D | Missense Mutation (SNP) | VAF 310/1051 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- DYNC2H1 | c.3931T>C p.S1311P | Missense Mutation (SNP) | VAF 26/856 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FNIP2 | c.3040A>G p.K1014E | Missense Mutation (SNP) | VAF 34/814 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- GNAT1 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 208/588 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GOLGA6C | c.2012A>G p.E671G | Missense Mutation (SNP) | VAF 91/805 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GTF2B | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 238/911 reads (26%) | called by muse, mutect2, varscan2
- GTF2IRD2B | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 137/589 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- H2BC4 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 71/563 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- HECTD4 | c.10270G>A p.G3424R | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HMCN1 | c.13022G>T p.G4341V | Missense Mutation (SNP) | VAF 120/948 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by mutect2, varscan2
- HP | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 127/536 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTATIP2 | c.-1-2A>G | Splice Site (SNP) | VAF 164/498 reads (33%) | called by muse, mutect2, varscan2
- IL11RA | c.77G>A p.C26Y | Missense Mutation (SNP) | VAF 150/498 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- IPMK | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 370/1161 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- ITPKA | c.1291C>A p.H431N | Missense Mutation (SNP) | VAF 37/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JADE3 | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 31/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNMA1 | c.3442C>T p.P1148S (on ENST00000286628 / NM_001161352.2; = p.P1090S on NM_002247.4) | Missense Mutation (SNP) | VAF 200/822 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by mutect2, varscan2
- KIF2A | c.558+3T>C | Splice Region (SNP) | VAF 211/822 reads (26%) | called by muse, mutect2, varscan2
- KL | c.1726G>C p.A576P | Missense Mutation (SNP) | VAF 42/619 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.756); called by muse, mutect2
- L3MBTL1 | c.1270G>A p.V424M (on ENST00000418998 / NM_001377303.1; = p.V334M on NM_015478.7) | Missense Mutation (SNP) | VAF 184/603 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- LCP1 | c.1057A>G p.T353A | Missense Mutation (SNP) | VAF 199/664 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LIMD1 | c.1864_1865del p.D622Lfs*17 | Frame Shift Del (DEL) | VAF 206/790 reads (26%) | called by pindel, varscan2
- LRP12 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 65/1226 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.176); called by muse, mutect2
- LRP1B | c.8307G>T p.Q2769H | Missense Mutation (SNP) | VAF 393/1186 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MLLT6 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 339/713 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- MMP25 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 231/788 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MORC4 | c.1452A>G p.K484= | Splice Region (SNP) | VAF 26/562 reads (5%) | called by muse, mutect2
- MOS | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 142/449 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUSK | c.1685A>C p.N562T | Missense Mutation (SNP) | VAF 502/1466 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MZF1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 188/702 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NADK2 | c.769G>T p.A257S (on ENST00000381937 / NM_001085411.3; = p.A94S on NM_153013.4) | Missense Mutation (SNP) | VAF 250/844 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NKX6-2 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 38/886 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSD2 | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 34/1018 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NSD3 | c.3197dup p.N1066Kfs*14 | Frame Shift Ins (INS) | VAF 335/1087 reads (31%) | called by mutect2, varscan2
- OBSCN | c.5552G>A p.G1851D | Missense Mutation (SNP) | VAF 42/360 reads (12%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); called by muse, varscan2
- ODF3B | c.418+2T>C p.X140_splice | Splice Site (SNP) | VAF 98/331 reads (30%) | called by muse, mutect2, varscan2
- OR6K6 | c.883G>T p.V295L (on ENST00000368144; = p.V271L on NM_001005184.1) | Missense Mutation (SNP) | VAF 150/1209 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHGA4 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 155/898 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PCNX2 | c.4111G>A p.A1371T | Missense Mutation (SNP) | VAF 50/1318 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- PDGFRA | c.1392_1415del p.L465_I472del | In Frame Del (DEL) | VAF 599/1382 reads (43%) | called by mutect2, pindel, varscan2
- PHKA2 | c.2836C>A p.L946I | Missense Mutation (SNP) | VAF 25/562 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2
- PHLPP2 | c.3148C>T p.P1050S | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.554); called by muse, mutect2
- PKHD1L1 | c.10000T>C p.S3334P | Missense Mutation (SNP) | VAF 259/549 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PPARGC1A | c.365A>C p.E122A | Missense Mutation (SNP) | VAF 638/1043 reads (61%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP1R32 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 213/630 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PRDM2 | c.4106A>C p.N1369T | Missense Mutation (SNP) | VAF 365/1101 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSD3 | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 312/917 reads (34%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PTGR1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 475/1455 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RERE | c.1418C>T p.T473I | Missense Mutation (SNP) | VAF 256/845 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- RHEB | c.555A>T p.*185Cext*6 | Nonstop Mutation (SNP) | VAF 48/992 reads (5%) | called by muse, mutect2
- RNF165 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 189/660 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- RNF19B | c.436_451del p.L146Afs*4 | Frame Shift Del (DEL) | VAF 82/400 reads (21%) | called by mutect2, pindel, varscan2
- RTF1 | c.1374G>A p.A458= | Splice Region (SNP) | VAF 303/875 reads (35%) | called by muse, mutect2, varscan2
- RYR2 | c.6555+2T>C p.X2185_splice | Splice Site (SNP) | VAF 214/691 reads (31%) | called by muse, mutect2, varscan2
- SBK3 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 124/388 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- SDAD1 | c.1001A>T p.N334I | Missense Mutation (SNP) | VAF 485/925 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- SEC14L1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 281/1109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA4C | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 222/778 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SGSM2 | c.1728G>A p.W576* (on ENST00000426855 / NM_001098509.2; = p.W621* on NM_014853.3) | Nonsense Mutation (SNP) | VAF 299/974 reads (31%) | called by muse, mutect2, varscan2
- SHANK3 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIGLEC11 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SLC35D3 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 217/717 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC35F3 | c.737C>T p.A246V (on ENST00000366617 / NM_001300845.1; = p.A315V on NM_173508.4) | Missense Mutation (SNP) | VAF 164/528 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC52A2 | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 211/583 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by mutect2, varscan2
- SMPD1 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 175/579 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP200 | c.3496C>T p.R1166C | Missense Mutation (SNP) | VAF 210/780 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2
- SNX31 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 36/834 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- SOCS6 | c.197dup p.N66Kfs*49 | Frame Shift Ins (INS) | VAF 372/1426 reads (26%) | called by pindel, varscan2
- SPAG17 | c.3829C>T p.P1277S | Missense Mutation (SNP) | VAF 314/1066 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SPTBN4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 155/544 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2225A>T p.D742V | Missense Mutation (SNP) | VAF 328/1043 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- STXBP5 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 122/736 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, varscan2
- TBC1D22B | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 225/737 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCHH | c.5558C>T p.T1853M | Missense Mutation (SNP) | VAF 87/638 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TRIM58 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRIP10 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 208/613 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TUBA1B | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 369/1240 reads (30%) | called by muse, mutect2, varscan2
- TUT7 | c.4043G>A p.R1348Q | Missense Mutation (SNP) | VAF 436/1358 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- UBE2G1 | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 345/1182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP9Y | c.6077A>G p.N2026S | Missense Mutation (SNP) | VAF 32/584 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UVSSA | c.1730G>A p.C577Y | Missense Mutation (SNP) | VAF 87/741 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK3 | c.1311dup p.L438Ifs*9 | Frame Shift Ins (INS) | VAF 63/564 reads (11%) | called by mutect2, pindel, varscan2
- XPOT | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 355/1297 reads (27%) | called by muse, mutect2, varscan2
- YES1 | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 183/597 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZBTB12 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 239/672 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZC3H6 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 196/563 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ZNF316 | c.2899G>A p.G967S | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT tolerated, low confidence (0.23); called by muse, mutect2, varscan2
- ZNF574 | c.1004T>A p.V335D | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF605 | c.1551G>C p.K517N | Missense Mutation (SNP) | VAF 289/926 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ABCC1 | c.4296C>T p.V1432= | Silent (SNP) | VAF 190/620 reads (31%) | catalogued as rs753509205, COSV100580477; called by muse, mutect2, varscan2
- ABCC10 | c.2598C>T p.G866= (on ENST00000372530 / NM_001198934.2; = p.G838= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 236/727 reads (32%) | catalogued as rs748097420, COSV55094711; called by muse, mutect2, varscan2
- ABCC3 | c.2949G>A p.A983= | Silent (SNP) | VAF 226/893 reads (25%) | catalogued as rs778958237; called by muse, mutect2, varscan2
- AC127029.3 | c.393C>T p.N131= | Silent (SNP) | VAF 372/1425 reads (26%) | catalogued as rs745988896; called by muse, varscan2
- ACHE | c.1608G>A p.A536= | Silent (SNP) | VAF 170/504 reads (34%) | catalogued as rs757575019; called by muse, mutect2, varscan2
- ACVR1B | c.201C>T p.R67= | Silent (SNP) | VAF 199/653 reads (30%) | catalogued as rs1353986407; called by muse, mutect2, varscan2
- ADGRL1 | c.4077C>T p.D1359= (on ENST00000340736 / NM_001008701.3; = p.D1354= on NM_014921.5) | Silent (SNP) | VAF 74/207 reads (36%) | catalogued as rs755252011; called by muse, mutect2, varscan2
- AGRN | c.3057G>A p.P1019= | Silent (SNP) | VAF 106/325 reads (33%) | catalogued as rs199554974; called by muse, mutect2
- AMPD1 | c.2205C>T p.G735= | Silent (SNP) | VAF 178/701 reads (25%) | catalogued as rs776996179, COSV62417080; called by muse, mutect2, varscan2
- ARFGEF3 | c.324C>T p.N108= | Silent (SNP) | VAF 403/1148 reads (35%) | catalogued as rs115941727; called by muse, mutect2, varscan2
- ARHGAP22 | c.1167C>T p.P389= | Silent (SNP) | VAF 109/389 reads (28%) | catalogued as rs1293763504, COSV50947031; called by muse, mutect2, varscan2
- ARHGEF3 | c.282G>A p.S94= | Silent (SNP) | VAF 442/1305 reads (34%) | catalogued as rs889756914; called by muse, mutect2, varscan2
- ASPHD1 | c.459C>T p.Y153= | Silent (SNP) | VAF 190/566 reads (34%) | catalogued as rs1314643314, COSV100435240; called by muse, mutect2, varscan2
- ATF7IP | c.2610T>C p.L870= | Silent (SNP) | VAF 310/952 reads (33%) | called by muse, mutect2, varscan2
- ATP1A4 | c.435C>T p.S145= | Silent (SNP) | VAF 293/939 reads (31%) | catalogued as rs780624299, COSV100927579, COSV63625681; called by muse, mutect2, varscan2
- ATP4A | c.2226A>G p.G742= | Silent (SNP) | VAF 259/683 reads (38%) | catalogued as rs986024114; called by muse, mutect2, varscan2
- BAIAP2L2 | c.544C>A p.R182= | Silent (SNP) | VAF 242/786 reads (31%) | catalogued as COSV100207250; called by muse, mutect2, varscan2
- BCAR1 | c.2607C>T p.A869= | Silent (SNP) | VAF 128/289 reads (44%) | catalogued as rs575562171; called by muse, mutect2, varscan2
- BCAS3 | c.1242C>T p.S414= | Silent (SNP) | VAF 215/861 reads (25%) | called by muse, mutect2, varscan2
- BRD8 | c.105C>T p.G35= | Silent (SNP) | VAF 192/793 reads (24%) | catalogued as rs183440093, COSV99136639; called by muse, mutect2, varscan2
- C1GALT1 | c.273C>T p.C91= | Silent (SNP) | VAF 32/1292 reads (2%) | called by muse, mutect2
- C1QL1 | c.34C>T p.L12= | Silent (SNP) | VAF 178/415 reads (43%) | called by muse, mutect2, varscan2
- C22orf23 | c.240G>A p.S80= | Silent (SNP) | VAF 312/842 reads (37%) | catalogued as rs746977617, COSV50778814; called by muse, mutect2, varscan2
- C9orf24 | c.609C>T p.G203= | Silent (SNP) | VAF 140/422 reads (33%) | catalogued as rs778876533, COSV99898022; called by muse, mutect2, varscan2
- CACNA1E | c.6747G>A p.T2249= (on ENST00000367573 / NM_001205293.3; = p.T2206= on NM_000721.4) | Silent (SNP) | VAF 132/486 reads (27%) | catalogued as COSV62384910; called by muse, mutect2, varscan2
- CCDC51 | c.213T>C p.I71= | Silent (SNP) | VAF 130/714 reads (18%) | called by muse, mutect2, varscan2
- CCL5 | c.54C>T p.C18= | Silent (SNP) | VAF 207/828 reads (25%) | catalogued as rs752445704; called by muse, mutect2, varscan2
- CD207 | c.657C>T p.A219= | Silent (SNP) | VAF 40/1308 reads (3%) | catalogued as rs781850322, COSV69651903; called by muse, mutect2
- CD320 | c.219C>T p.R73= | Silent (SNP) | VAF 276/905 reads (30%) | called by muse, mutect2, varscan2
- CD6 | c.768C>T p.G256= | Silent (SNP) | VAF 157/482 reads (33%) | catalogued as rs774907838, COSV57837967; called by muse, mutect2, varscan2
- CDC20B | c.1116C>T p.S372= | Silent (SNP) | VAF 243/796 reads (31%) | catalogued as rs748116618, COSV57055469; called by muse, mutect2, varscan2
- CDC42BPB | c.3261C>T p.G1087= | Silent (SNP) | VAF 147/589 reads (25%) | catalogued as rs377411407; called by muse, mutect2, varscan2
- CELSR1 | c.6486C>T p.H2162= | Silent (SNP) | VAF 225/731 reads (31%) | catalogued as rs146626077; called by muse, mutect2, varscan2
- CHML | c.453C>T p.D151= | Silent (SNP) | VAF 433/1213 reads (36%) | catalogued as rs148297941; called by muse, mutect2, varscan2
- CHST3 | c.1053C>T p.S351= | Silent (SNP) | VAF 155/405 reads (38%) | catalogued as rs1341613061, COSV64151379; called by muse, mutect2, varscan2
- CLK3 | c.1053C>T p.N351= (on ENST00000395066 / NM_001130028.1; = p.N203= on NM_003992.4) | Silent (SNP) | VAF 232/973 reads (24%) | catalogued as rs759157880; called by muse, mutect2, varscan2
- CLSPN | c.3897G>A p.S1299= | Silent (SNP) | VAF 248/969 reads (26%) | catalogued as rs370131184; called by muse, mutect2, varscan2
- CLUH | c.288C>T p.N96= (on ENST00000435359; = p.N134= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 226/863 reads (26%) | catalogued as rs749041840; called by muse, mutect2
- CNNM2 | c.2583G>A p.T861= | Silent (SNP) | VAF 250/744 reads (34%) | catalogued as rs772898439, COSV63996899; called by muse, mutect2, varscan2
- CNOT1 | c.612C>T p.D204= | Silent (SNP) | VAF 240/498 reads (48%) | catalogued as COSV57778997; called by muse, mutect2, varscan2
- COASY | c.1413C>T p.A471= | Silent (SNP) | VAF 207/924 reads (22%) | catalogued as rs751893869; called by muse, mutect2, varscan2
- COL8A1 | c.1467G>T p.G489= | Silent (SNP) | VAF 24/622 reads (4%) | called by muse, mutect2
- CTNND2 | c.2904C>T p.H968= | Silent (SNP) | VAF 386/1241 reads (31%) | catalogued as rs764796131, COSV58925854; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTTNBP2 | c.27G>A p.E9= | Silent (SNP) | VAF 26/574 reads (5%) | called by muse, mutect2
- DACT3 | c.516C>T p.S172= | Silent (SNP) | VAF 175/497 reads (35%) | catalogued as rs1247689004; called by muse, mutect2, varscan2
- DAXX | c.2169T>C p.S723= | Silent (SNP) | VAF 264/828 reads (32%) | called by muse, mutect2, varscan2
- DEPDC1 | c.330G>A p.S110= | Silent (SNP) | VAF 153/546 reads (28%) | catalogued as rs766624676; called by muse, mutect2
- DHX30 | c.321C>T p.I107= (on ENST00000445061 / NM_138615.3; = p.I68= on NM_014966.3) | Silent (SNP) | VAF 194/638 reads (30%) | catalogued as rs375356846; called by muse, mutect2, varscan2
- DRD4 | c.681C>T p.R227= | Silent (SNP) | VAF 115/422 reads (27%) | catalogued as rs776632059; called by muse, varscan2
- DUS3L | c.279C>T p.P93= | Silent (SNP) | VAF 18/554 reads (3%) | catalogued as rs1254511043; called by muse, mutect2
- DYRK2 | c.1212T>C p.D404= (on ENST00000344096 / NM_006482.3; = p.D331= on NM_003583.4) | Silent (SNP) | VAF 247/889 reads (28%) | called by muse, mutect2, varscan2
- E2F2 | c.1185G>A p.A395= | Silent (SNP) | VAF 114/378 reads (30%) | catalogued as rs752620979; called by muse, mutect2, varscan2
- EBF3 | c.1692G>A p.A564= (on ENST00000355311 / NM_001375392.1; = p.A519= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 171/641 reads (27%) | catalogued as rs779933101; called by muse, mutect2, varscan2
- EEF2K | c.873G>A p.T291= | Silent (SNP) | VAF 224/761 reads (29%) | catalogued as rs140938002, COSV53778094; called by muse, mutect2, varscan2
- EFCAB6 | c.3642C>T p.D1214= | Silent (SNP) | VAF 162/547 reads (30%) | catalogued as rs375120220; called by muse, mutect2, varscan2
- EGFLAM | c.498G>A p.A166= | Silent (SNP) | VAF 275/968 reads (28%) | catalogued as rs758620907; called by muse, mutect2, varscan2
- FAM220A | c.486G>A p.P162= | Silent (SNP) | VAF 131/475 reads (28%) | catalogued as rs142897377, COSV57625877; called by muse, mutect2, varscan2
- FBXL19 | c.615G>A p.P205= | Silent (SNP) | VAF 174/493 reads (35%) | called by muse, mutect2, varscan2
- FGD5 | c.3759C>T p.C1253= | Silent (SNP) | VAF 204/702 reads (29%) | catalogued as rs1485689497, COSV53241917; called by muse, mutect2, varscan2
- FGFR3 | c.960C>T p.D320= | Silent (SNP) | VAF 28/618 reads (5%) | catalogued as rs914236518; called by muse, mutect2
- FN1 | c.2028A>G p.V676= | Silent (SNP) | VAF 295/861 reads (34%) | called by muse, varscan2
- FOXD4L3 | c.837C>T p.A279= | Silent (SNP) | VAF 37/262 reads (14%) | called by mutect2, varscan2
- GBGT1 | c.795C>T p.F265= | Silent (SNP) | VAF 185/550 reads (34%) | catalogued as rs1399259047; called by muse, mutect2, varscan2
- GH2 | c.594G>A p.K198= | Silent (SNP) | VAF 565/1381 reads (41%) | catalogued as rs1180893574; called by muse, mutect2, varscan2
- GID8 | c.360G>A p.A120= | Silent (SNP) | VAF 400/1122 reads (36%) | catalogued as rs562845173; called by muse, mutect2, varscan2
- GRIN3B | c.2844G>A p.A948= | Silent (SNP) | VAF 42/538 reads (8%) | catalogued as rs775561433; called by muse, mutect2
- GRM5 | c.2946C>T p.C982= (on ENST00000305447 / NM_001143831.2; = p.C950= on NM_000842.4) | Silent (SNP) | VAF 162/426 reads (38%) | called by muse, mutect2, varscan2
- GRM5 | c.2874C>T p.S958= (on ENST00000305447 / NM_001143831.2; = p.S926= on NM_000842.4) | Silent (SNP) | VAF 20/530 reads (4%) | catalogued as COSV59595113; called by muse, mutect2
- GSDME | c.816G>A p.A272= | Silent (SNP) | VAF 265/898 reads (30%) | catalogued as rs144907090; called by muse, mutect2, varscan2
- HEATR6 | c.1587G>A p.A529= | Silent (SNP) | VAF 337/1202 reads (28%) | catalogued as rs200325351; called by muse, mutect2, varscan2
- HELZ2 | c.4332C>A p.R1444= (on ENST00000467148 / NM_001037335.2; = p.R875= on NM_033405.3) | Silent (SNP) | VAF 129/355 reads (36%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.714C>T p.Y238= | Silent (SNP) | VAF 73/694 reads (11%) | catalogued as rs539163968, COSV51449138; called by muse, mutect2, varscan2
- HTR3D | c.1107C>A p.G369= (on ENST00000382489 / NM_001163646.2; = p.G194= on NM_182537.3) | Silent (SNP) | VAF 227/769 reads (30%) | catalogued as COSV100488367; called by muse, mutect2, varscan2
- IGF2R | c.4326C>T p.D1442= | Silent (SNP) | VAF 312/981 reads (32%) | catalogued as rs780426967; called by muse, mutect2, varscan2
- ING1 | c.684C>T p.G228= | Silent (SNP) | VAF 258/756 reads (34%) | catalogued as COSV58170320; called by muse, mutect2, varscan2
- INTS11 | c.1245C>T p.G415= | Silent (SNP) | VAF 308/863 reads (36%) | catalogued as rs771263622; called by muse, mutect2, varscan2
- INTS9 | c.1212C>T p.D404= | Silent (SNP) | VAF 369/1113 reads (33%) | catalogued as rs548025826; called by muse, mutect2, varscan2
- JAG2 | c.1644C>T p.G548= | Silent (SNP) | VAF 215/591 reads (36%) | catalogued as rs1375692084; called by muse, mutect2, varscan2
- JAK3 | c.2634G>A p.L878= | Silent (SNP) | VAF 218/704 reads (31%) | catalogued as rs762599452; called by muse, mutect2, varscan2
- KCNU1 | c.1383T>C p.I461= | Silent (SNP) | VAF 238/746 reads (32%) | called by muse, mutect2, varscan2
- KIF1B | c.921G>A p.R307= (on ENST00000377086 / NM_001365952.1; = p.R301= on NM_015074.3) | Silent (SNP) | VAF 43/1180 reads (4%) | called by muse, mutect2
- KLB | c.1995G>A p.S665= | Silent (SNP) | VAF 15/436 reads (3%) | catalogued as COSV57301223; called by muse, mutect2
- LOXL3 | c.1206C>T p.A402= | Silent (SNP) | VAF 227/643 reads (35%) | catalogued as rs559055791; called by muse, mutect2, varscan2
- LPAR2 | c.459C>T p.G153= | Silent (SNP) | VAF 146/439 reads (33%) | catalogued as rs761108199; called by muse, mutect2, varscan2
- LPCAT4 | c.420C>A p.P140= | Silent (SNP) | VAF 355/1074 reads (33%) | called by muse, mutect2, varscan2
- LRP1 | c.10695C>T p.S3565= | Silent (SNP) | VAF 191/553 reads (35%) | catalogued as rs999908047; called by muse, mutect2, varscan2
- LRRC75A | c.591A>G p.L197= (on ENST00000470794 / NM_001113567.3; = p.T159A on NM_207387.4) | Silent (SNP) | VAF 204/735 reads (28%) | catalogued as rs556233808; called by muse, mutect2, varscan2
- LTA | c.315C>T p.G105= | Silent (SNP) | VAF 213/731 reads (29%) | catalogued as COSV69304278; called by muse, mutect2, varscan2
- LY75 | c.3576G>A p.G1192= | Silent (SNP) | VAF 96/1272 reads (8%) | catalogued as rs750390764; called by muse, mutect2
- MALRD1 | c.6321C>T p.T2107= | Silent (SNP) | VAF 170/641 reads (27%) | catalogued as rs1306165478; called by muse, mutect2, varscan2
- MCF2L | c.1674G>A p.A558= (on ENST00000375608; = p.A526= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 173/556 reads (31%) | catalogued as rs147346793, COSV100982130; called by muse, mutect2, varscan2
- MCTP1 | c.1395G>A p.S465= | Silent (SNP) | VAF 355/1160 reads (31%) | catalogued as rs1188495020, COSV56527956; called by muse, mutect2, varscan2
- MDH2 | c.297G>A p.P99= | Silent (SNP) | VAF 223/762 reads (29%) | catalogued as rs147689281; called by muse, mutect2, varscan2
- MEF2D | c.642C>T p.N214= | Silent (SNP) | VAF 244/854 reads (29%) | catalogued as rs1208819338, COSV61730314; called by muse, mutect2, varscan2
- MEGF8 | c.4557C>T p.P1519= (on ENST00000251268 / NM_001271938.2; = p.P1452= on NM_001410.3) | Silent (SNP) | VAF 292/909 reads (32%) | catalogued as rs941289827, COSV99235366; called by muse, mutect2, varscan2
- MEGF8 | c.7773C>T p.G2591= (on ENST00000251268 / NM_001271938.2; = p.G2524= on NM_001410.3) | Silent (SNP) | VAF 128/327 reads (39%) | catalogued as rs375633770; called by muse, mutect2, varscan2
- MIB2 | c.1338C>T p.G446= | Silent (SNP) | VAF 265/798 reads (33%) | catalogued as rs772077260; called by muse, mutect2, varscan2
- MKRN2 | c.402C>T p.S134= | Silent (SNP) | VAF 98/922 reads (11%) | catalogued as rs757190739, COSV50103819; called by muse, mutect2
- MLNR | c.6C>T p.G2= | Silent (SNP) | VAF 138/468 reads (29%) | called by muse, mutect2, varscan2
- MMP1 | c.1167C>T p.T389= | Silent (SNP) | VAF 232/931 reads (25%) | called by muse, mutect2, varscan2
- MPEG1 | c.1716C>T p.C572= | Silent (SNP) | VAF 227/666 reads (34%) | catalogued as rs199723583; called by muse, mutect2, varscan2
- MPPED1 | c.942G>A p.P314= | Silent (SNP) | VAF 178/625 reads (28%) | catalogued as rs761966125, COSV68838297; called by muse, mutect2, varscan2
- MPZ | c.372G>A p.T124= | Silent (SNP) | VAF 365/1106 reads (33%) | catalogued as rs536830537, COSV60667586; called by muse, mutect2, varscan2
- MRC2 | c.2688C>T p.S896= | Silent (SNP) | VAF 407/899 reads (45%) | catalogued as rs1027912370; called by muse, mutect2, varscan2
- MUC17 | c.7191T>C p.T2397= | Silent (SNP) | VAF 239/707 reads (34%) | called by muse, mutect2, varscan2
- MYLIP | c.1290C>T p.H430= | Silent (SNP) | VAF 343/984 reads (35%) | catalogued as rs778903550, COSV100785944, COSV62766292; called by muse, mutect2, varscan2
- MYO15A | c.8799C>T p.F2933= | Silent (SNP) | VAF 220/696 reads (32%) | catalogued as rs766439265; called by muse, mutect2, varscan2
- NCL | c.1896C>T p.D632= | Silent (SNP) | VAF 264/972 reads (27%) | catalogued as rs755358839, COSV59546186; called by muse, mutect2, varscan2
- NEDD9 | c.1623C>T p.D541= | Silent (SNP) | VAF 193/615 reads (31%) | catalogued as rs532153778; called by muse, mutect2, varscan2
- NHSL1 | c.255G>A p.P85= | Silent (SNP) | VAF 29/934 reads (3%) | catalogued as rs1389009492, COSV58683801; called by muse, mutect2
- NTPCR | c.396G>A p.T132= | Silent (SNP) | VAF 44/962 reads (5%) | catalogued as rs201925982; called by muse, mutect2
- OAS3 | c.2121C>T p.N707= | Silent (SNP) | VAF 64/1329 reads (5%) | catalogued as rs867710602, COSV57448549; called by muse, mutect2
- ORAI2 | c.318C>T p.A106= | Silent (SNP) | VAF 87/552 reads (16%) | catalogued as rs754654017; called by muse, mutect2, varscan2
- OSBPL9 | c.567C>T p.H189= | Silent (SNP) | VAF 140/523 reads (27%) | catalogued as rs370193883; called by muse, mutect2, varscan2
- PAK4 | c.834C>T p.P278= | Silent (SNP) | VAF 130/348 reads (37%) | catalogued as rs542325747; called by muse, mutect2, varscan2
- PBXIP1 | c.327C>T p.T109= | Silent (SNP) | VAF 210/606 reads (35%) | catalogued as rs778525250, COSV63777588; called by muse, mutect2, varscan2
- PCDHA13 | c.144C>T p.I48= | Silent (SNP) | VAF 227/569 reads (40%) | catalogued as rs868915208, COSV56495461; called by muse, mutect2, varscan2
- PCDHB12 | c.1449C>T p.N483= | Silent (SNP) | VAF 110/359 reads (31%) | catalogued as COSV53401727; called by muse, mutect2, varscan2
- PCDHB13 | c.2157G>A p.A719= | Silent (SNP) | VAF 115/368 reads (31%) | catalogued as COSV53393520, COSV99507142; called by muse, mutect2, varscan2
- PDE8A | c.2140C>A p.R714= | Silent (SNP) | VAF 232/917 reads (25%) | called by muse, mutect2, varscan2
- PKD1L3 | c.3690A>G p.Q1230= | Silent (SNP) | VAF 208/497 reads (42%) | called by muse, mutect2, varscan2
- PLCB3 | c.3636C>T p.H1212= | Silent (SNP) | VAF 173/440 reads (39%) | catalogued as rs774283163; called by muse, mutect2, varscan2
- PLEKHM1 | c.855G>A p.E285= | Silent (SNP) | VAF 218/880 reads (25%) | catalogued as rs767747878; called by muse, mutect2, varscan2
- PLXNB2 | c.1956C>T p.N652= | Silent (SNP) | VAF 187/643 reads (29%) | called by muse, mutect2, varscan2
- PM20D1 | c.909C>A p.P303= | Silent (SNP) | VAF 189/664 reads (28%) | catalogued as COSV65649002; called by muse, mutect2, varscan2
- PNO1 | c.243A>C p.P81= | Silent (SNP) | VAF 317/1041 reads (30%) | catalogued as COSV54561927; called by muse, mutect2, varscan2
- POLD1 | c.723C>T p.F241= | Silent (SNP) | VAF 187/600 reads (31%) | catalogued as rs764364345, COSV70956464; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPARD | c.1200G>A p.L400= | Silent (SNP) | VAF 76/698 reads (11%) | called by muse, mutect2, varscan2
- PPFIA3 | c.2850C>T p.G950= | Silent (SNP) | VAF 180/571 reads (32%) | catalogued as rs765574283, COSV53256982, COSV53258759; called by muse, mutect2, varscan2
- PPP4R1 | c.1161T>C p.A387= (on ENST00000400556 / NM_001042388.3; = p.A370= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/884 reads (5%) | called by muse, mutect2
- PRRT3 | c.1242G>A p.T414= | Silent (SNP) | VAF 150/494 reads (30%) | called by muse, mutect2, varscan2
- PXDNL | c.2367C>T p.R789= | Silent (SNP) | VAF 131/388 reads (34%) | catalogued as COSV100682401; called by muse, mutect2, varscan2
- QRICH2 | c.4068C>T p.S1356= | Silent (SNP) | VAF 83/1382 reads (6%) | catalogued as rs146550737; called by muse, mutect2
- RABGAP1L | c.321G>A p.P107= | Silent (SNP) | VAF 167/626 reads (27%) | catalogued as rs189440280; called by muse, mutect2, varscan2
- RFPL2 | c.879G>A p.P293= | Silent (SNP) | VAF 66/956 reads (7%) | catalogued as rs559935317, COSV99964429; called by muse, mutect2
- RGL1 | c.999G>A p.S333= (on ENST00000360851 / NM_001297672.2; = p.S368= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 398/1317 reads (30%) | catalogued as rs375471211; called by muse, mutect2, varscan2
- RNF213 | c.11715C>T p.S3905= | Silent (SNP) | VAF 243/1056 reads (23%) | catalogued as rs775719348, COSV60394329; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPTOR | c.2367C>T p.R789= | Silent (SNP) | VAF 388/894 reads (43%) | catalogued as rs777751384; called by muse, mutect2, varscan2
- RTP5 | c.489C>T p.S163= | Silent (SNP) | VAF 119/380 reads (31%) | catalogued as rs749581337; called by muse, mutect2, varscan2
- SBNO2 | c.3837G>A p.P1279= | Silent (SNP) | VAF 126/409 reads (31%) | catalogued as rs1180758571; called by muse, mutect2, varscan2
- SEMA4C | c.198C>T p.Y66= | Silent (SNP) | VAF 197/608 reads (32%) | catalogued as rs1468761348, COSV100560862; called by muse, mutect2, varscan2
- SEPTIN4 | c.1179T>C p.Y393= | Silent (SNP) | VAF 201/818 reads (25%) | called by muse, mutect2, varscan2
- SLC24A3 | c.1353G>A p.A451= | Silent (SNP) | VAF 266/865 reads (31%) | called by muse, mutect2, varscan2
- SLC2A11 | c.1014C>T p.R338= (on ENST00000345044 / NM_001024938.4; = p.R345= on NM_030807.5) | Silent (SNP) | VAF 245/783 reads (31%) | catalogued as rs140785969; called by muse, mutect2, varscan2
- SLC52A1 | c.1218G>A p.P406= | Silent (SNP) | VAF 167/487 reads (34%) | catalogued as rs781275131; called by muse, mutect2, varscan2
- SLITRK6 | c.2007T>C p.T669= | Silent (SNP) | VAF 313/1008 reads (31%) | called by muse, mutect2, varscan2
- SNX33 | c.1575C>T p.F525= | Silent (SNP) | VAF 127/452 reads (28%) | catalogued as rs377607517; called by muse, mutect2, varscan2
- SOCS6 | c.378G>A p.S126= | Silent (SNP) | VAF 196/658 reads (30%) | catalogued as rs748033311, COSV101205847; called by muse, mutect2, varscan2
- SPATA31A7 | c.1584G>A p.S528= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1332802249; called by mutect2, varscan2
- SSRP1 | c.465C>T p.D155= | Silent (SNP) | VAF 276/979 reads (28%) | catalogued as rs768771466, COSV53478149; called by muse, mutect2, varscan2
- STAB1 | c.2574C>A p.S858= | Silent (SNP) | VAF 204/711 reads (29%) | called by muse, mutect2, varscan2
- STAC2 | c.978C>T p.N326= | Silent (SNP) | VAF 100/879 reads (11%) | catalogued as rs770870439; called by muse, mutect2, varscan2
- STRADB | c.108C>A p.T36= | Silent (SNP) | VAF 43/1000 reads (4%) | catalogued as rs1379739041, COSV52043614; called by muse, mutect2
- SUPT6H | c.4767C>T p.Y1589= | Silent (SNP) | VAF 213/645 reads (33%) | catalogued as rs113506234; called by muse, mutect2, varscan2
- SV2C | c.828C>T p.G276= | Silent (SNP) | VAF 201/767 reads (26%) | catalogued as rs928271738, COSV59221209; called by muse, mutect2, varscan2
- TBCE | c.912G>A p.T304= (on ENST00000366601; = p.T367= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 320/938 reads (34%) | catalogued as rs750203834; called by muse, mutect2, varscan2
- THBS1 | c.1980C>T p.N660= | Silent (SNP) | VAF 225/750 reads (30%) | catalogued as rs148609363; called by muse, mutect2, varscan2
- TMEM201 | c.1758C>T p.H586= | Silent (SNP) | VAF 144/531 reads (27%) | catalogued as rs1035885323; called by muse, mutect2, varscan2
- TMEM220 | c.192A>G p.A64= | Silent (SNP) | VAF 263/917 reads (29%) | catalogued as rs756808409; called by muse, mutect2, varscan2
- TMEM51 | c.402C>T p.Y134= | Silent (SNP) | VAF 232/804 reads (29%) | catalogued as rs748204095; called by muse, varscan2
- TMOD3 | c.834G>A p.A278= | Silent (SNP) | VAF 300/819 reads (37%) | catalogued as rs769931590; called by muse, mutect2, varscan2
- TNFRSF11A | c.1416C>T p.C472= | Silent (SNP) | VAF 154/446 reads (35%) | catalogued as rs771249524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNN | c.687C>T p.S229= | Silent (SNP) | VAF 143/502 reads (28%) | catalogued as COSV53429596; called by muse, mutect2, varscan2
- TOR4A | c.234C>A p.T78= | Silent (SNP) | VAF 137/586 reads (23%) | catalogued as rs777997327; called by muse, mutect2, varscan2
- TRIM37 | c.828C>T p.Y276= | Silent (SNP) | VAF 447/1143 reads (39%) | catalogued as rs776019614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPM2 | c.447G>A p.T149= | Silent (SNP) | VAF 172/587 reads (29%) | catalogued as rs542411061; called by muse, mutect2, varscan2
- TRPV4 | c.687G>A p.S229= | Silent (SNP) | VAF 182/645 reads (28%) | catalogued as rs545660001, COSV55680059, COSV55684357; called by muse, mutect2, varscan2
- TTF1 | c.738C>T p.A246= | Silent (SNP) | VAF 227/788 reads (29%) | catalogued as rs996290144, COSV57507597; called by muse, mutect2, varscan2
- TTLL5 | c.3666C>T p.C1222= | Silent (SNP) | VAF 338/1102 reads (31%) | catalogued as rs141359185; called by muse, mutect2, varscan2
- TTN | c.18G>A p.P6= | Silent (SNP) | VAF 247/859 reads (29%) | catalogued as rs755302800, COSV59895874; called by muse, mutect2, varscan2
- TTYH3 | c.486C>T p.P162= | Silent (SNP) | VAF 113/419 reads (27%) | catalogued as rs1305231886; called by muse, mutect2, varscan2
- UBA2 | c.54C>T p.G18= | Silent (SNP) | VAF 233/707 reads (33%) | catalogued as rs1472036650, COSV55824660, COSV55826287; called by muse, mutect2, varscan2
- UGT3A2 | c.354G>A p.A118= | Silent (SNP) | VAF 196/791 reads (25%) | catalogued as rs191531345; called by muse, mutect2, varscan2
- USP19 | c.906C>T p.Y302= | Silent (SNP) | VAF 294/799 reads (37%) | catalogued as rs946816637, COSV59730638; called by muse, mutect2, varscan2
- VIRMA | c.1482C>T p.H494= | Silent (SNP) | VAF 317/1030 reads (31%) | catalogued as rs777152713; called by muse, mutect2, varscan2
- VWA5B2 | c.3720G>A p.A1240= | Silent (SNP) | VAF 119/386 reads (31%) | catalogued as rs1391739912; called by muse, mutect2, varscan2
- WNT11 | c.978C>T p.V326= | Silent (SNP) | VAF 220/679 reads (32%) | catalogued as rs764115045; called by muse, mutect2, varscan2
- XKR8 | c.525G>A p.S175= | Silent (SNP) | VAF 252/888 reads (28%) | catalogued as rs371532571; called by muse, mutect2, varscan2
- ZBTB20 | c.1263G>A p.P421= (on ENST00000474710 / NM_001164342.2; = p.P348= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 233/767 reads (30%) | catalogued as rs768828042, COSV61869413; called by muse, mutect2, varscan2
- ZDBF2 | c.3666C>T p.S1222= | Silent (SNP) | VAF 284/1079 reads (26%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.1278G>A p.S426= | Silent (SNP) | VAF 171/577 reads (30%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.1074C>T p.C358= | Silent (SNP) | VAF 122/402 reads (30%) | catalogued as rs774482536; called by muse, varscan2
- ZFR2 | c.840C>T p.C280= | Silent (SNP) | VAF 18/453 reads (4%) | catalogued as rs867295717, COSV53603181; called by muse, mutect2
- ZNF2 | c.1071C>T p.N357= (on ENST00000611147 / NM_001291605.2; = p.N344= on NM_021088.4) | Silent (SNP) | VAF 27/815 reads (3%) | catalogued as COSV54637002; called by muse, mutect2
- ZNF264 | c.1557G>A p.S519= | Silent (SNP) | VAF 305/983 reads (31%) | catalogued as rs1218880103; called by muse, mutect2, varscan2
- ZNF282 | c.1962C>T p.G654= | Silent (SNP) | VAF 22/668 reads (3%) | catalogued as rs972880986; called by muse, mutect2
- ZNF423 | c.2115C>T p.C705= (on ENST00000563137 / NM_001379286.1; = p.C697= on NM_015069.4) | Silent (SNP) | VAF 45/732 reads (6%) | catalogued as rs141743740; called by muse, mutect2
- ZNF444 | c.219C>T p.P73= | Silent (SNP) | VAF 172/538 reads (32%) | catalogued as rs778261562, COSV61363503; called by muse, mutect2, varscan2
- ZNF713 | c.207G>A p.A69= (on ENST00000633730 / NM_001366796.2; = p.A82= on NM_182633.3) | Silent (SNP) | VAF 44/1426 reads (3%) | called by muse, mutect2
- ZYX | c.1482C>T p.P494= | Silent (SNP) | VAF 160/650 reads (25%) | catalogued as rs757437427; called by muse, mutect2, varscan2
- A1BG | c.70+27T>C | Intron (SNP) | VAF 191/518 reads (37%) | called by muse, mutect2, varscan2
- ACAA1 | c.323+54C>A | Intron (SNP) | VAF 120/316 reads (38%) | called by muse, mutect2, varscan2
- ACAP3 | c.*99G>A | 3'UTR (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.*251C>T | 3'UTR (SNP) | VAF 12/206 reads (6%) | catalogued as rs1047501896; called by muse, mutect2
- AGK | c.976-99A>G | Intron (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- AICDA | c.427+26G>A | Intron (SNP) | VAF 138/403 reads (34%) | catalogued as rs1335177070, COSV57563910; called by muse, mutect2, varscan2
- AKR1C4 | c.*41T>C | 3'UTR (SNP) | VAF 152/521 reads (29%) | called by muse, mutect2, varscan2
- AP3B2 | c.772-39C>T | Intron (SNP) | VAF 110/326 reads (34%) | catalogued as rs1395025479; called by muse, mutect2, varscan2
- APTX | c.-4-80G>A | Intron (SNP) | VAF 21/57 reads (37%) | catalogued as rs989790949; called by muse, mutect2, varscan2
- ATRX | c.7071+50A>G | Intron (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- B3GALT6 | c.*77C>T | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, varscan2
- BCL3 | c.*14del | 3'UTR (DEL) | VAF 126/448 reads (28%) | catalogued as rs746428325; called by mutect2, pindel, varscan2
- BRD2 | c.*87G>A | 3'UTR (SNP) | VAF 31/111 reads (28%) | catalogued as rs1000069582; called by muse, mutect2
- BTG3 | c.174-57A>G | Intron (SNP) | VAF 106/345 reads (31%) | catalogued as rs1569184929; called by muse, mutect2, varscan2
- C1QTNF12 | c.640+61C>T | Intron (SNP) | VAF 15/164 reads (9%) | catalogued as rs1424468840; called by muse, mutect2
- C22orf39 | c.*13C>T | 3'UTR (SNP) | VAF 122/389 reads (31%) | called by muse, mutect2, varscan2
- CALB1 | c.451-78G>A | Intron (SNP) | VAF 76/173 reads (44%) | called by muse, mutect2, varscan2
- CARD11 | c.*8G>A | 3'UTR (SNP) | VAF 114/400 reads (29%) | catalogued as rs377661624; called by muse, mutect2, varscan2
- CARM1 | c.-69G>A | 5'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as rs1452581165; called by muse, mutect2
- CBLIF | c.1192+23C>T | Intron (SNP) | VAF 213/654 reads (33%) | catalogued as rs372611471; called by muse, mutect2, varscan2
- CCN6 | c.-13C>T | 5'UTR (SNP) | VAF 156/585 reads (27%) | called by muse, mutect2, varscan2
- CCT3 | c.32-70C>T | Intron (SNP) | VAF 39/688 reads (6%) | catalogued as rs562449395; called by muse, mutect2
- CD22 | c.2208+56C>T | Intron (SNP) | VAF 18/208 reads (9%) | catalogued as rs955180438; called by muse, mutect2
- CD6 | c.-26C>T | 5'UTR (SNP) | VAF 86/306 reads (28%) | catalogued as rs769226671; called by muse, mutect2, varscan2
- CEP164 | c.4164-45C>T | Intron (SNP) | VAF 46/150 reads (31%) | catalogued as rs536728673; called by muse, mutect2, varscan2
- CHD1L | c.1270+66C>T | Intron (SNP) | VAF 78/244 reads (32%) | catalogued as rs1041297745; called by muse, mutect2, varscan2
- CLEC12A | chr12:9951257 T>G | 5'Flank (SNP) | VAF 45/172 reads (26%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-169C>T | Intron (SNP) | VAF 110/547 reads (20%) | catalogued as rs767540869; called by muse, varscan2
- CORO7 | c.2457+35G>A | Intron (SNP) | VAF 71/213 reads (33%) | catalogued as rs371511082; called by muse, mutect2, varscan2
- CRIP2 | c.197-70G>A | Intron (SNP) | VAF 46/161 reads (29%) | called by muse, mutect2, varscan2
- CYTH3 | c.711+19G>A | Intron (SNP) | VAF 133/486 reads (27%) | catalogued as rs758538852; called by muse, mutect2, varscan2
- DMTF1 | c.2173+28C>T | Intron (SNP) | VAF 103/571 reads (18%) | called by muse, mutect2, varscan2
- DNASE1 | chr16:3658329 C>T | 3'Flank (SNP) | VAF 9/65 reads (14%) | called by muse, mutect2, varscan2
- ELAC2 | c.1659+86G>A | Intron (SNP) | VAF 58/233 reads (25%) | catalogued as rs745563227; called by muse, mutect2, varscan2
- ELOB | c.*390C>T | 3'UTR (SNP) | VAF 203/724 reads (28%) | called by muse, mutect2, varscan2
- EPB41L4A | c.99+55394T>C | Intron (SNP) | VAF 128/284 reads (45%) | catalogued as rs1561609761; called by muse, mutect2, varscan2
- ETS2 | c.-480A>G | 5'UTR (SNP) | VAF 78/267 reads (29%) | called by muse, mutect2, varscan2
- FAM131B | c.91-50C>T | Intron (SNP) | VAF 92/255 reads (36%) | catalogued as rs372186934; called by muse, mutect2, varscan2
- FAM131C | c.*77C>T | 3'UTR (SNP) | VAF 18/152 reads (12%) | catalogued as rs1292782705; called by muse, mutect2
- FARP1 | c.171+31165T>A | Intron (SNP) | VAF 266/938 reads (28%) | called by muse, mutect2, varscan2
- FBXO40 | c.*44G>A | 3'UTR (SNP) | VAF 102/392 reads (26%) | catalogued as rs772431558; called by muse, mutect2, varscan2
- FIG4 | c.1750+96_1750+98del | Intron (DEL) | VAF 44/142 reads (31%) | called by mutect2, pindel
- GABRD | c.554-94C>T | Intron (SNP) | VAF 58/175 reads (33%) | catalogued as rs1397209243; called by muse, mutect2, varscan2
- GIT2 | c.406-9G>A | Intron (SNP) | VAF 164/975 reads (17%) | catalogued as rs200008112; called by muse, mutect2, varscan2
- GNLY | c.*73C>T | 3'UTR (SNP) | VAF 151/519 reads (29%) | catalogued as rs1257297550; called by muse, mutect2, varscan2
- GPR149 | c.*41G>A | 3'UTR (SNP) | VAF 75/221 reads (34%) | catalogued as rs374234455; called by muse, mutect2, varscan2
- GTF3A | c.303-604G>T | Intron (SNP) | VAF 122/670 reads (18%) | called by muse, mutect2, varscan2
- GTPBP4 | c.*16C>T | 3'UTR (SNP) | VAF 189/519 reads (36%) | catalogued as rs369588499; called by muse, mutect2, varscan2
- IQSEC1 | c.2848-1603G>A | Intron (SNP) | VAF 168/577 reads (29%) | catalogued as rs1011164875; called by muse, mutect2, varscan2
- ISL2 | c.59-15G>A | Intron (SNP) | VAF 140/385 reads (36%) | called by muse, mutect2, varscan2
- JCAD | c.*27G>A | 3'UTR (SNP) | VAF 226/789 reads (29%) | catalogued as rs996152761, COSV100948417; called by muse, mutect2, varscan2
- KCNK7 | chr11:65595803 C>T | 5'Flank (SNP) | VAF 126/433 reads (29%) | catalogued as rs754448821; called by muse, mutect2, varscan2
- KCTD16 | c.*16G>A | 3'UTR (SNP) | VAF 210/640 reads (33%) | catalogued as rs747862089; called by muse, varscan2
- KIF1B | c.2115+6647G>A | Intron (SNP) | VAF 296/1141 reads (26%) | catalogued as rs754969112, COSV99823596; called by muse, mutect2, varscan2
- KLHDC9 | c.*61C>T | 3'UTR (SNP) | VAF 177/451 reads (39%) | catalogued as rs570398111; called by muse, mutect2, varscan2
- KTN1 | c.4069+42T>C | Intron (SNP) | VAF 133/390 reads (34%) | called by muse, mutect2, varscan2
- LAMP1 | c.*65T>C | 3'UTR (SNP) | VAF 118/299 reads (39%) | called by muse, mutect2, varscan2
- LAT | c.163+66G>A | Intron (SNP) | VAF 80/296 reads (27%) | catalogued as rs1054552052; called by muse, varscan2
- LAX1 | c.-216C>T | 5'UTR (SNP) | VAF 329/935 reads (35%) | catalogued as rs368729091; called by muse, mutect2, varscan2
- LCN1 | c.*128del | 3'UTR (DEL) | VAF 221/673 reads (33%) | called by mutect2, pindel, varscan2
- LEUTX | c.-56G>A | 5'UTR (SNP) | VAF 44/116 reads (38%) | catalogued as rs117937250; called by muse, mutect2, varscan2
- LGALS7 | chr19:38769820 C>T | 3'Flank (SNP) | VAF 20/669 reads (3%) | called by muse, mutect2
- LY6G5C | c.346-78del | Intron (DEL) | VAF 36/106 reads (34%) | called by mutect2, pindel, varscan2
- MALT1 | c.-59C>T | 5'UTR (SNP) | VAF 114/392 reads (29%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.371-15805C>T | Intron (SNP) | VAF 164/698 reads (23%) | catalogued as rs904867060; called by muse, varscan2
- MAPK8IP3 | c.3017+31C>T | Intron (SNP) | VAF 18/501 reads (4%) | catalogued as rs868691609; called by muse, mutect2
- MAPKAP1 | c.1066+73G>A | Intron (SNP) | VAF 58/196 reads (30%) | catalogued as rs774781203; called by muse, mutect2, varscan2
- MEGF11 | c.900-64G>T | Intron (SNP) | VAF 106/247 reads (43%) | called by muse, mutect2, varscan2
- MFAP4 | c.6+92G>T | Intron (SNP) | VAF 235/685 reads (34%) | called by muse, mutect2, varscan2
- MFSD14A | c.1103-42del | Intron (DEL) | VAF 82/260 reads (32%) | catalogued as rs754154717; called by mutect2, varscan2
- MLLT10 | c.240+18008G>A | Intron (SNP) | VAF 271/947 reads (29%) | catalogued as rs764402984; called by muse, mutect2, varscan2
- MRNIP | c.449+83G>A | Intron (SNP) | VAF 40/150 reads (27%) | catalogued as rs181713982; called by muse, mutect2, varscan2
- MTRF1L | c.260-98C>T | Intron (SNP) | VAF 47/164 reads (29%) | called by muse, mutect2, varscan2
- MYO1C | c.*7C>T | 3'UTR (SNP) | VAF 193/600 reads (32%) | catalogued as rs548792139; called by muse, mutect2, varscan2
- NAT9 | c.334+26C>T | Intron (SNP) | VAF 97/1144 reads (8%) | catalogued as rs199848210; called by muse, mutect2
- NDUFS1 | c.*93del | 3'UTR (DEL) | VAF 50/147 reads (34%) | catalogued as rs200446477; ClinVar: uncertain significance; called by mutect2, varscan2
- NEB | c.18826-2931C>T | Intron (SNP) | VAF 139/460 reads (30%) | catalogued as rs1458048713, CM042506; called by muse, mutect2, varscan2
- NHS | c.853-2080G>A | Intron (SNP) | VAF 197/301 reads (65%) | catalogued as rs755068848, COSV66271079; called by muse, mutect2, varscan2
- NISCH | c.1528+592G>A | Intron (SNP) | VAF 269/877 reads (31%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1303-99G>A | Intron (SNP) | VAF 60/203 reads (30%) | catalogued as rs1023356819; called by muse, mutect2, varscan2
- OBSCN | c.18662-2301C>T | Intron (SNP) | VAF 250/767 reads (33%) | catalogued as COSV99477722; called by muse, mutect2, varscan2
- OGFOD3 | c.699+13G>A | Intron (SNP) | VAF 187/738 reads (25%) | catalogued as rs1437376326; called by mutect2, varscan2
- PAM16 | c.4-77C>T | Intron (SNP) | VAF 12/225 reads (5%) | catalogued as rs1478423106; called by muse, mutect2
- PCSK4 | c.855+31G>A | Intron (SNP) | VAF 20/456 reads (4%) | called by muse, mutect2
- PCYT2 | c.759+49G>A | Intron (SNP) | VAF 272/502 reads (54%) | catalogued as rs376042396; called by muse, mutect2, varscan2
- PGK1 | c.1115-77C>T | Intron (SNP) | VAF 61/107 reads (57%) | called by muse, mutect2, varscan2
- PIP5K1C | c.1920+1415G>T | Intron (SNP) | VAF 57/478 reads (12%) | called by muse, mutect2, varscan2
- PODN | c.457-19C>T | Intron (SNP) | VAF 90/232 reads (39%) | catalogued as rs375360473; called by muse, varscan2
- POLA2 | c.744+50C>T | Intron (SNP) | VAF 93/310 reads (30%) | catalogued as rs887978950; called by muse, mutect2, varscan2
- PPM1F | c.985+18C>T | Intron (SNP) | VAF 121/374 reads (32%) | catalogued as rs774920514, COSV54284059; called by muse, mutect2, varscan2
- PPP6R1 | c.*11C>T | 3'UTR (SNP) | VAF 114/390 reads (29%) | catalogued as rs936570376; called by muse, mutect2, varscan2
- PSMC6 | c.757+62del | Intron (DEL) | VAF 94/385 reads (24%) | catalogued as rs1024042550; called by mutect2, pindel, varscan2
- PTBP1 | c.435+12C>T | Intron (SNP) | VAF 192/582 reads (33%) | catalogued as rs201979033; called by muse, mutect2, varscan2
- RAC2 | c.-88G>A | 5'UTR (SNP) | VAF 64/179 reads (36%) | catalogued as rs971073256, COSV50774737; called by muse, mutect2, varscan2
- RFXAP | c.*64del | 3'UTR (DEL) | VAF 133/444 reads (30%) | called by mutect2, pindel, varscan2
- RGMA | c.15-800C>T | Intron (SNP) | VAF 75/226 reads (33%) | catalogued as COSV61236157; called by muse, mutect2
- RHPN2 | c.1645-37A>G | Intron (SNP) | VAF 124/411 reads (30%) | called by muse, mutect2, varscan2
29 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 29 other) are not listed here.
